Somatic mutation profile of tumor specimen HTMCP-03-06-02347-01A (aliquot HTMCP-03-06-02347-01A-01D-9392) from CGCI case HTMCP-03-06-02347, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 43.6 years (15,917 days).
Specimen HTMCP-03-06-02347-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 656b05bb-da9e-4484-9fd8-19b07bc12e41.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02347-10A (Blood Derived Normal), aliquot HTMCP-03-06-02347-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9064b69b-b49a-423a-8467-3412df233c28

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Nonsense Mutation 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1597C>T p.R533C (on ENST00000399959; = p.R534C on NM_001356.5) | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1555954284, COSV67863588, COSV67863748; ClinVar: likely pathogenic; called by muse, mutect2
- ERICH3 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755547640; called by mutect2, varscan2
- FRMPD2 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.731); catalogued as rs777616214, COSV100563736; called by muse, mutect2, varscan2
- GLI2 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as rs571690193, COSV58045775; ClinVar: uncertain significance; called by mutect2, varscan2
- PSG6 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1398812733, COSV51838168; called by muse, mutect2, varscan2
- SF3B1 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV59230816; called by muse, mutect2, varscan2
- SLC7A3 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.751); catalogued as rs767788043; called by muse, mutect2, varscan2
- ZNF263 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs138118006; called by mutect2, varscan2
- ACACA | c.3740G>T p.G1247V | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.382); called by muse, mutect2
- AKAP9 | c.4070C>A p.T1357N | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ANKRD36 | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- C2CD6 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CAPN8 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- CFAP54 | c.2516A>C p.K839T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- F9 | c.1264A>C p.T422P | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ICE2 | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNQ5 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- KDM3A | c.2372C>T p.S791L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIP12 | c.5483G>A p.W1828* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- TRPS1 | c.449_452del p.T150Rfs*27 (on ENST00000220888 / NM_001330599.2; = p.T163Rfs*27 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/168 reads (18%) | called by mutect2, pindel, varscan2
- ZNF341 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DYNC2H1 | c.10939C>T p.L3647= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- FBN2 | c.6459T>C p.D2153= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- INO80 | c.3750A>C p.S1250= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as rs1487389113; called by muse, mutect2, varscan2
- NIN | c.2667C>T p.V889= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV55406056; called by muse, mutect2
- PHC3 | c.2724G>A p.L908= (on ENST00000494943 / NM_001308116.2; = p.L920= on NM_024947.4) | Silent (SNP) | VAF 57/208 reads (27%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.1626G>A p.T542= (on ENST00000379409; = p.T490= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs368689384; called by muse, varscan2
- TLL1 | c.1011C>T p.I337= | Silent (SNP) | VAF 25/150 reads (17%) | catalogued as rs541355348, COSV50306345; called by muse, mutect2, varscan2
- YME1L1 | c.1113T>C p.L371= (on ENST00000326799 / NM_139312.3; = p.L314= on NM_014263.4) | Silent (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- TTC6 | c.358-1315A>G | Intron (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
